Gene-level copy-number profile of tumor specimen TCGA-V1-A8WV-01A from TCGA case TCGA-V1-A8WV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.6e81de8d-3f4d-4653-8e9e-be22f76dcf8f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A8WV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51f508e6-5d0a-49a6-9a55-b80d24d7432b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 631; copy number 2: 19,097; copy number 3: 19,851; copy number 4: 16,479; copy number 5: 1,869; copy number 6: 1,418; copy number 7: 356; copy number 9: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A8WV-01A-11D-A376-01): tumor purity 0.48, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:42,086,110–44,109,886, 98 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 374 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,340,998, 12 genes, copy number 9: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene, copy number 9: TRGV5P.
- chr8:129,241,228–129,484,142, 5 genes, copy number 9: AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:137,105,352–145,066,685, 222 genes, copy number 7 (broad region; genes not listed).
- chr19:56,922,018–58,605,223, 134 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
